Gene-level copy-number profile of tumor specimen TCGA-IG-A625-01A from TCGA case TCGA-IG-A625, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 60.4 years (22,070 days).
Specimen TCGA-IG-A625-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.3f55cf88-7ca4-48ac-8cd0-2f5b33948710.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-IG-A625-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d07404be-430e-434b-b373-7aa788ca0c13

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 40; copy number 1: 1; copy number 2: 5,549; copy number 4: 40,891; copy number 5: 2,182; copy number 6: 6,561; copy number 7: 13; copy number 8: 2,912; copy number 9: 1,646; copy number 14: 15; copy number 18: 7.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-IG-A625-01A-11D-A31T-01): tumor purity 0.74, ploidy 2.2, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 17 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:140,992,543–140,992,659, 1 gene: Y_RNA.
- chr9:21,802,636–22,455,740, 16 genes (within-gene range 0–6): MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,653 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:93,843,764–193,697,811, 1,635 genes, copy number 9 (broad region; genes not listed).
- chr4:72,280,969–73,258,798, 8 genes, copy number 9–18: ADAMTS3, AC095056.1, HNRNPA1P67, RNU4ATAC9P, RNU6ATAC5P, COX18, ANKRD17, HMGA1P2.
- chr4:73,263,960–73,264,084, 1 gene, copy number 18: AC053527.1.
- chr17:82,614,562–82,751,196, 9 genes, copy number 9 (within-gene range 5–9): WDR45B, AC124283.5, RAB40B, MIR4525, AC024361.2, FN3KRP, AC024361.3, FN3K, AC024361.1.

Autosomal genes at a single copy (total copy number 1): 1. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
